Surgical pathology report (de-identified scan), TCGA case TCGA-DH-5140, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-5140-01A (Primary Tumor).

[page 1 of 2]
Case Type: [REDACTED]

[REDACTED] female presents today for craniotomy for resection of left temporal brain tumor. History of headaches, left eye blurriness. MRI showed abnormality in left temporal area. GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name and hospital #:

- A. Tumor
- B. Tumor #2

The specimen is received fresh and consists of a 6.5 x 4.0 x 1.5 cm rectangular piece of cerebral cortex and underlying subcortical white matter. The deep surfaces are cauterized and focally hemorrhagic. The meningeal surface has a prominent surface vasculature with the usual gyral and focused pattern. Sectioning reveals the majority of the specimen to have a clear demarcation between apparent cortex and adjacent white matter layers, however, along one deep edge the gray matter is obscured by an ill-defined firm white lesion measuring 2.2 x 1.5 x 1.0 cm in greatest dimension. A representative section of the lesion is submitted for frozen section. Frozen section diagnosis is, "Infiltrating glioma with focal high grade areas; final diagnosis deferred to permanent sections," per [REDACTED]. The frozen tissue is submitted for permanent processing in cassette FSA1. Additional representative sections of the lesion are submitted in cassettes A2-A6. A representative section of uninvolved cortex is submitted in cassette A7.

The specimen is received without fixative and consists of a 2.5 x 1.8 x 0.4 cm rectangular piece of cortical brain tissue. Sectioning reveals the demarcation between the gray and adjacent white matter layers to be smudged and ill-defined. No discrete lesion is grossly identified. A representative portion of the tissue is submitted for frozen section. Frozen section diagnosis is, "Infiltrating glioma," per [REDACTED]. The frozen tissue is submitted for permanent processing in cassette FSB1. The remaining tissue is entirely submitted in cassettes B2-B4. [REDACTED]

DIAGNOSIS:

- A. "Tumor":
Anaplastic mixed glioma (oligoastrocytoma) (WHO Grade III) (see comment)
- B. "Tumor #2":
Anaplastic mixed glioma (oligoastrocytoma) (see comment)

COMMENT: This infiltrating glioma extensively infiltrates gray and white matter. The predominant pattern is that of a diffuse anaplastic astrocytoma with moderate nuclear and cellular pleomorphism and significant mitotic activity (5 mitoses per ten high power fields in some

[page 2 of 2]
areas). However, areas having a very uniform and distinctly oligodendroglomatous histologic appearance are also present, although these are in the minority. The Ki67 labeling index is about 10-15% overall. These findings support the diagnosis. The tumor is negative for PTEN and EGFRvIII. The pattern of GFAP immunoreactivity suggests positive staining of both neoplastic and reactive elements.

The status of chromosomes 1p and 19q will be determined by fluorescence in situ hybridization and reported as an addendum to this report. "I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]
Pathologist

Electronically signed [REDACTED]

ADDENDUM:

Chromosomes 1p and 19 q analysis:

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) WAS PERFORMED ON REPRESENTATIVE PARAFFIN-EMBEDDED TUMOR TISSUE (VYSIS). IN THIS CASE, NO DELETIONS OF 1P OR 19Q WERE IDENTIFIED. [REDACTED]

REFERENCES:

[REDACTED]

Source: NCI Genomic Data Commons file 0e088e71-23a2-4e5b-a9e3-dbdf340ad282 (TCGA-DH-5140.4F8B82C9-5185-4994-AC3D-A0F3A9EEFD61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).